Somatic mutation profile of tumor specimen C3L-09554-05 (aliquot CPT0497160006) from CPTAC case C3L-09554, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 79.9 years (29,181 days).
Specimen C3L-09554-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa4d9d97-55ca-44a6-9cac-c762f2b35c7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09554-32 (Blood Derived Normal), aliquot CPT0497230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/469eba31-4d02-4096-bdc3-29cffa7452f6

The open-access MAF lists 1,708 somatic variants for this specimen: 1,230 protein-altering or splice-affecting, 417 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 897, Silent 417, Frame Shift Del 209, Frame Shift Ins 52, Nonsense Mutation 41, Intron 36, Splice Region 13, 3'UTR 12, In Frame Del 9, Splice Site 9, 5'UTR 5, 3'Flank 4.

Variants (750 of 1,708; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 53/455 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- ASPA | c.244dup p.M82Nfs*8 | Frame Shift Ins (INS) | VAF 24/148 reads (16%) | catalogued as rs756198538; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CFTR | c.50del p.F17Sfs*8 | Frame Shift Del (DEL) | VAF 60/380 reads (16%) | catalogued as rs397508714, CM135530; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- CIB2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 41/293 reads (14%) | catalogued as rs201845656, CM164140; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 48/324 reads (15%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- KIF7 | c.3331C>T p.R1111* | Nonsense Mutation (SNP) | VAF 43/344 reads (13%) | catalogued as rs778139192, CM129877, COSV51546453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 41/323 reads (13%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 74/698 reads (11%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.233del p.N78Ifs*7 | Frame Shift Del (DEL) | VAF 26/221 reads (12%) | catalogued as rs1438566555; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGT | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 39/373 reads (10%) | catalogued as rs201317502; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 46/352 reads (13%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF469 | c.6360del p.Q2121Sfs*51 (on ENST00000437464; = p.Q2149Sfs*51 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 71/642 reads (11%) | catalogued as rs886044697; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA10 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52228673; called by muse, mutect2
- ABCA2 | c.3934G>A p.E1312K (on ENST00000614293; = p.E1282K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/476 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.726); catalogued as rs764897224, COSV55799388, COSV99688272; called by muse, mutect2, varscan2
- ABCA7 | c.5161T>A p.F1721I | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV54035462; called by muse, mutect2, varscan2
- ABCA9 | c.3498del p.F1166Lfs*5 | Frame Shift Del (DEL) | VAF 30/324 reads (9%) | catalogued as rs1177267466; called by pindel, varscan2
- ABCB8 | c.2153C>T p.A718V (on ENST00000297504 / NM_001282291.2; = p.A701V on NM_007188.5) | Missense Mutation (SNP) | VAF 128/615 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs750888931; called by muse, mutect2, varscan2
- ABCC2 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV64985081; called by muse, mutect2, varscan2
- ABCF2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 118/581 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs752398993; called by muse, mutect2, varscan2
- AC008397.2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 53/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326213719, COSV53210247; called by muse, mutect2, varscan2
- AC092835.1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.924); catalogued as rs961655587; called by muse, mutect2, varscan2
- ACKR4 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 32/437 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs543522851; called by muse, mutect2
- ACSL3 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV62481738; called by muse, mutect2, varscan2
- ADAM10 | c.1288A>G p.N430D | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs765293675; called by muse, mutect2, varscan2
- ADAM29 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 45/549 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746641739, COSV63663321; called by muse, mutect2
- ADAMTSL5 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750955914; called by muse, mutect2, varscan2
- ADAP1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs945204362; called by muse, mutect2
- ADCYAP1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs8192594, COSV52485636, COSV52486264; called by muse, mutect2, varscan2
- ADGRB1 | c.1318dup p.Q440Pfs*8 | Frame Shift Ins (INS) | VAF 78/586 reads (13%) | catalogued as rs772974645; called by mutect2, varscan2
- ADGRG5 | c.1485C>T p.Y495= | Splice Region (SNP) | VAF 49/308 reads (16%) | catalogued as rs370635864, COSV61083030; called by muse, mutect2, varscan2
- AGAP1 | c.1438C>A p.Q480K | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); catalogued as COSV100364673; called by muse, mutect2, varscan2
- AGAP2 | c.2770C>A p.R924S (on ENST00000547588 / NM_001122772.2; = p.R568S on NM_014770.4) | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV99223049; called by muse, mutect2, varscan2
- AHCTF1 | c.3565A>G p.S1189G (on ENST00000366508; = p.S1163G on NM_015446.5) | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs369797943; called by muse, mutect2, varscan2
- AHNAK2 | c.7681G>A p.G2561S | Missense Mutation (SNP) | VAF 73/524 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs372983447; called by muse, mutect2, varscan2
- AICDA | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV99984430; called by muse, mutect2, varscan2
- AKAP17A | c.1060_1062del p.E354del | In Frame Del (DEL) | VAF 86/736 reads (12%) | catalogued as rs752474646; called by mutect2, pindel, varscan2
- ALDH1A2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs137957671; called by muse, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 67/552 reads (12%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALDH3B1 | c.638del p.G213Afs*118 | Frame Shift Del (DEL) | VAF 65/582 reads (11%) | catalogued as rs770500704; called by mutect2, pindel, varscan2
- ALDOA | c.746G>A p.G249E (on ENST00000642816 / NM_001243177.4; = p.G195E on NM_184041.5) | Missense Mutation (SNP) | VAF 47/506 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV57632343; called by muse, mutect2
- ALG1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs992880561, COSV52157476; called by muse, mutect2, varscan2
- ALG5 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs781456350; called by muse, mutect2, varscan2
- ALKBH6 | c.247G>A p.V83M (on ENST00000252984 / NM_001297701.2; = p.V111M on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/578 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.86); catalogued as rs377096899; called by muse, mutect2
- ALOX5 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.194); catalogued as rs756201127; called by muse, mutect2, varscan2
- AMPD3 | c.1330G>A p.G444S (on ENST00000396553 / NM_001025389.2; = p.G453S on NM_000480.3) | Missense Mutation (SNP) | VAF 63/495 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756895453, COSV67331333; called by muse, mutect2, varscan2
- ANK2 | c.5692A>C p.T1898P | Missense Mutation (SNP) | VAF 68/563 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.572); catalogued as rs767662891; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7084C>T p.R2362* | Nonsense Mutation (SNP) | VAF 42/363 reads (12%) | catalogued as COSV99783811; called by muse, mutect2, varscan2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 38/274 reads (14%) | catalogued as rs868780344; called by mutect2, varscan2
- ANKRD52 | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs760776825; called by muse, mutect2, varscan2
- ANO9 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs752943942; called by muse, mutect2
- AP000812.4 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1369599724; called by muse, mutect2, varscan2
- AP1M2 | c.1052del p.G351Afs*5 | Frame Shift Del (DEL) | VAF 34/332 reads (10%) | catalogued as rs1490250889; called by mutect2, pindel
- AP3S1 | c.297del p.K99Nfs*11 | Frame Shift Del (DEL) | VAF 35/281 reads (12%) | catalogued as COSV57475065; called by mutect2, pindel, varscan2
- AP4S1 | c.228C>T p.N76= | Splice Region (SNP) | VAF 31/233 reads (13%) | catalogued as rs144109125; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP5Z1 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 127/489 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs371379357; called by muse, mutect2, varscan2
- APOB | c.2746G>T p.A916S | Missense Mutation (SNP) | VAF 31/426 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.066); catalogued as COSV51937211, COSV51956149; called by muse, mutect2
- AQP2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1279852191, CM153550; called by muse, mutect2, varscan2
- ARHGAP22 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 72/552 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs750730446, COSV99984848; called by muse, mutect2, varscan2
- ARHGEF40 | c.2767C>T p.R923W | Missense Mutation (SNP) | VAF 73/624 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs903600980, COSV53881662; called by muse, mutect2, varscan2
- ARID1B | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs544895806, COSV51651464; called by muse, mutect2, varscan2
- ARID1B | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1282942992, COSV51657347; called by muse, mutect2
- ARMC5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 83/710 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs772950226, COSV99192588; called by muse, mutect2, varscan2
- ARSI | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 74/519 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.103); catalogued as rs780152906, COSV100155982; called by muse, mutect2, varscan2
- ASPH | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751131305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD3A | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 73/605 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as rs746218239; called by muse, varscan2
- ATG10 | c.483del p.F161Lfs*12 | Frame Shift Del (DEL) | VAF 32/362 reads (9%) | catalogued as rs1186430519; called by mutect2, pindel
- ATP10B | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs746958421; called by muse, mutect2
- ATP12A | c.1780C>A p.P594T | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99517168; called by muse, mutect2, varscan2
- ATP1A3 | c.197T>A p.L66* (on ENST00000545399 / NM_001256214.2; = p.L53* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 35/349 reads (10%) | catalogued as COSV57491807; called by muse, mutect2, varscan2
- ATP1A4 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 54/523 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139315814; called by muse, mutect2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 41/369 reads (11%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- BAHCC1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 79/568 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs782553150, COSV57024709; called by muse, mutect2, varscan2
- BARHL2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776386545; called by muse, mutect2, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 82/481 reads (17%) | catalogued as CM025285, COSV52257903; called by mutect2, pindel, varscan2
- BFAR | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 35/459 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs752156727, COSV55493098; called by muse, mutect2
- BIVM-ERCC5 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs140917545; called by muse, mutect2
- BTBD17 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 67/617 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767680213, COSV64730918; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 65/517 reads (13%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C18orf32 | c.54dup p.F19Ifs*15 | Frame Shift Ins (INS) | VAF 49/474 reads (10%) | catalogued as rs1193367786; called by mutect2, pindel, varscan2
- C1QL2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 99/757 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs755186486; called by muse, mutect2, varscan2
- C2CD2L | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333792707; called by muse, mutect2
- C6 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 36/519 reads (7%) | catalogued as rs776817489, COSV54705154, COSV54716775; called by muse, mutect2
- C6orf132 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 68/685 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as rs1040769614; called by muse, mutect2
- C6orf132 | c.1674_1675del p.P559Nfs*10 | Frame Shift Del (DEL) | VAF 58/482 reads (12%) | catalogued as rs749378297; called by pindel, varscan2
- CACNA1A | c.5983C>T p.R1995C | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs903596182; called by muse, mutect2, varscan2
- CACNA1A | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.961); catalogued as rs1239474432, COSV100801941; called by muse, mutect2, varscan2
- CACNA1S | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 37/470 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146903750; ClinVar: uncertain significance; called by muse, mutect2
- CACNA2D4 | c.808G>T p.G270* | Nonsense Mutation (SNP) | VAF 30/332 reads (9%) | catalogued as rs1555185749; called by muse, mutect2
- CACNG4 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1427963530; called by muse, mutect2, varscan2
- CAMK1D | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331020416, COSV66608393; called by muse, mutect2, varscan2
- CAND1 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs771246650; called by muse, mutect2, varscan2
- CAPN3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349313665, CM052831, CM119415, COSV58818997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 54/238 reads (23%) | catalogued as rs770159446; called by mutect2, varscan2
- CCDC142 | c.1730G>A p.G577D (on ENST00000393965 / NM_001365575.2; = p.G570D on NM_032779.4) | Missense Mutation (SNP) | VAF 57/515 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs1221093048; called by muse, mutect2, varscan2
- CCDC17 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51970601; called by muse, mutect2, varscan2
- CCDC182 | c.64del p.M22* | Frame Shift Del (DEL) | VAF 52/435 reads (12%) | catalogued as rs1567992795; called by mutect2, pindel, varscan2
- CCDC39 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs564200203; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 53/328 reads (16%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC69 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs772342301; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 32/246 reads (13%) | catalogued as rs762553129; called by mutect2, varscan2
- CCNT1 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs1199274008; called by muse, mutect2
- CCT8L2 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746225083, COSV63463488; called by muse, mutect2, varscan2
- CD9 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs201524346; called by muse, mutect2, varscan2
- CDC20 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.364); catalogued as rs754185453, COSV60522835; called by muse, mutect2, varscan2
- CDH18 | c.1162T>C p.Y388H | Missense Mutation (SNP) | VAF 44/463 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99937993; called by muse, mutect2
- CDK12 | c.544_546del p.E182del | In Frame Del (DEL) | VAF 58/432 reads (13%) | catalogued as rs955200004; called by mutect2, pindel, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 44/236 reads (19%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP295 | c.5045dup p.S1683Kfs*2 | Frame Shift Ins (INS) | VAF 40/362 reads (11%) | catalogued as rs762289202; called by mutect2, varscan2
- CFAP54 | c.3668T>C p.L1223P | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV101598559; called by muse, mutect2
- CHAD | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 68/564 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs1355883526; called by muse, mutect2, varscan2
- CHRDL1 | c.584A>G p.E195G (on ENST00000372045; = p.E201G on NM_145234.4) | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.979); catalogued as rs1340265274; called by muse, mutect2
- CHRM3 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 66/429 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.174); catalogued as COSV55104749; called by muse, mutect2, varscan2
- CHST2 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 150/655 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV58885358; called by muse, mutect2, varscan2
- CIART | c.809del p.P270Lfs*15 | Frame Shift Del (DEL) | VAF 74/556 reads (13%) | catalogued as rs1560055008; called by mutect2, pindel, varscan2
- CILP2 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 87/738 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774681895; called by muse, mutect2, varscan2
- CILP2 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 62/604 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1254400933, COSV52275905; called by muse, mutect2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 43/250 reads (17%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as rs779015086; called by muse, mutect2, varscan2
- COL14A1 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs775543009, COSV52846651; called by muse, mutect2, varscan2
- COL22A1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 85/636 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs139591204; called by muse, mutect2, varscan2
- COL26A1 | c.1300G>A p.V434M (on ENST00000313669 / NM_001278563.3; = p.V432M on NM_133457.4) | Missense Mutation (SNP) | VAF 60/606 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as rs748839305; called by muse, mutect2
- COL28A1 | c.2691del p.V898Wfs*18 | Frame Shift Del (DEL) | VAF 91/497 reads (18%) | catalogued as rs766010947; called by mutect2, pindel, varscan2
- COL4A4 | c.3479G>T p.G1160V | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636474; called by muse, mutect2, varscan2
- COL6A3 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 37/516 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs764614021, COSV55091345; called by muse, mutect2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 52/316 reads (16%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- CPNE2 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 46/423 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs771489237, COSV51960904, COSV99321388; called by muse, mutect2, varscan2
- CPNE5 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs758788529; called by muse, mutect2, varscan2
- CPNE7 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1481938041, COSV99255103; called by muse, varscan2
- CR1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.151); catalogued as rs748011435, COSV65458887; called by muse, mutect2
- CR1 | c.3209del p.P1070Qfs*22 | Frame Shift Del (DEL) | VAF 48/362 reads (13%) | catalogued as rs765016539; called by mutect2, pindel, varscan2
- CRB1 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1349714528, COSV66348868; called by muse, mutect2, varscan2
- CROCC | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 48/720 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs373111310; called by muse, mutect2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 36/272 reads (13%) | catalogued as rs769538822; called by mutect2, varscan2
- CSNK1A1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as COSV55793968; called by muse, mutect2, varscan2
- CTNNB1 | c.1255T>C p.C419R | Missense Mutation (SNP) | VAF 37/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62712494; called by muse, mutect2
- CTNND1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 56/407 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs773141675, COSV104420726; called by muse, mutect2, varscan2
- CTSG | c.763del p.L255Cfs*3 | Frame Shift Del (DEL) | VAF 39/309 reads (13%) | catalogued as rs764116259; called by mutect2, pindel, varscan2
- CYP46A1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as rs774289118, COSV55894075; called by muse, mutect2
- CYP4F12 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs776517845, COSV61173202; called by muse, varscan2
- DAB2IP | c.731G>A p.R244H (on ENST00000408936; = p.R216H on NM_032552.3) | Missense Mutation (SNP) | VAF 59/452 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1463043286, COSV52266491, COSV99405267; called by muse, varscan2
- DACT3 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 82/812 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs1268399774; called by muse, mutect2
- DAPK3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs200205146, COSV56665373; called by muse, mutect2, varscan2
- DCAF12L2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 79/714 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1047080686, COSV63580676, COSV63584176; called by muse, mutect2, varscan2
- DCAF15 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs1394679445; called by muse, varscan2
- DCHS1 | c.8972G>A p.R2991Q | Missense Mutation (SNP) | VAF 56/513 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs200152314, COSV54999477; called by muse, mutect2, varscan2
- DCHS2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 60/748 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100252539; called by muse, mutect2
- DCST1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs142018467; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs778036194; called by mutect2, varscan2
- DENND2A | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 124/595 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs573861843, COSV52054083; called by muse, mutect2, varscan2
- DENND3 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 87/603 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs376429101; called by muse, mutect2, varscan2
- DISC1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 49/478 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs193024019; called by muse, mutect2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 103/850 reads (12%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by mutect2, pindel, varscan2
- DNAH17 | c.11573G>A p.R3858Q | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as rs752345814; called by muse, mutect2, varscan2
- DNAH5 | c.7501C>T p.R2501W | Missense Mutation (SNP) | VAF 73/642 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354589314, COSV54232187; called by muse, mutect2, varscan2
- DOC2A | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 55/497 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs202009086; called by muse, mutect2, varscan2
- DPCD | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs371695974; called by muse, mutect2
- DPYSL2 | c.1281C>T p.S427= | Splice Region (SNP) | VAF 22/209 reads (11%) | catalogued as rs776276751; called by muse, mutect2, varscan2
- DRC3 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs774076446; called by muse, mutect2, varscan2
- DUSP22 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 67/628 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs140673019, COSV60531870; called by muse, varscan2
- EDA | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 79/633 reads (12%) | catalogued as CM093364; called by muse, mutect2, varscan2
- EDEM3 | c.1974del p.F658Lfs*4 | Frame Shift Del (DEL) | VAF 40/312 reads (13%) | catalogued as rs1173052284; called by mutect2, varscan2
- EGR1 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs371059427; called by muse, mutect2, varscan2
- EIF4G1 | c.3613C>T p.R1205C (on ENST00000346169 / NM_198241.3; = p.R1010C on NM_004953.5) | Missense Mutation (SNP) | VAF 97/508 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs776741558, CM131885, COSV59990924; called by muse, mutect2, varscan2
- EIPR1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376371713; called by muse, mutect2
- EMILIN1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 54/642 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1221738236, COSV100980218; called by muse, mutect2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | catalogued as rs770453803; called by mutect2, varscan2
- ENTPD6 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 45/456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750480721, COSV61751882; called by muse, mutect2
- EPB41L4B | c.633G>A p.A211= | Splice Region (SNP) | VAF 45/297 reads (15%) | catalogued as rs370668187; called by muse, mutect2, varscan2
- EPM2AIP1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV51625246; called by muse, mutect2, varscan2
- EPS8L1 | c.1086del p.P363Rfs*12 (on ENST00000201647 / NM_133180.3; = p.P236Rfs*12 on NM_017729.3) | Frame Shift Del (DEL) | VAF 71/534 reads (13%) | catalogued as rs746955003, COSV99136727; called by mutect2, varscan2
- EPSTI1 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs561807314; called by muse, mutect2, varscan2
- ERFL | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 57/531 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs951575192, COSV61526463; called by muse, mutect2, varscan2
- ERN2 | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 58/564 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780525550; called by muse, mutect2, varscan2
- ERO1A | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV101193684; called by muse, mutect2, varscan2
- ESRRG | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 25/332 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.47); catalogued as rs774655818, COSV63155622; called by muse, mutect2
- EVPL | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 71/658 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs761584250, COSV56917252; called by muse, mutect2, varscan2
- F2RL3 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 65/544 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs751430141, COSV50186246; called by muse, mutect2, varscan2
- FAM178B | c.1838T>G p.I613S (on ENST00000490605 / NM_001122646.3; = p.I53S on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59967711; called by muse, mutect2, varscan2
- FAM214A | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99958011; called by muse, mutect2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 86/684 reads (13%) | catalogued as COSV63726734; called by pindel, varscan2
- FAM83D | c.1337T>C p.M446T | Missense Mutation (SNP) | VAF 77/552 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1383409590; called by muse, mutect2, varscan2
- FAT3 | c.4200dup p.X1400_splice | Splice Site (INS) | VAF 29/250 reads (12%) | catalogued as rs1160251707; called by mutect2, pindel, varscan2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 46/437 reads (11%) | catalogued as rs1566257864; called by mutect2, pindel, varscan2
- FBXL19 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 79/576 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1455701481; called by muse, mutect2, varscan2
- FBXL6 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 41/381 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as rs200807701; called by muse, mutect2, varscan2
- FBXO24 | c.1206G>T p.Q402H (on ENST00000241071 / NM_033506.3; = p.Q440H on NM_012172.5) | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99575650; called by muse, mutect2, varscan2
- FERD3L | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs145174585, COSV51761804, COSV51763651; called by muse, mutect2, varscan2
- FGF23 | c.89del p.P30Hfs*10 | Frame Shift Del (DEL) | VAF 47/489 reads (10%) | catalogued as COSV52977356; called by mutect2, pindel, varscan2
- FGFR4 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 34/317 reads (11%) | catalogued as rs756449612; called by muse, mutect2, varscan2
- FLII | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1470122964, COSV58943364; called by muse, mutect2
- FLNA | c.3370G>A p.V1124M | Missense Mutation (SNP) | VAF 76/764 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781842942; ClinVar: likely benign; called by muse, mutect2
- FLT4 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56125468; called by muse, mutect2, varscan2
- FNBP1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760469089, COSV63090232; called by muse, mutect2
- FNDC1 | c.2067del p.G690Afs*47 | Frame Shift Del (DEL) | VAF 72/650 reads (11%) | catalogued as COSV99796347; called by mutect2, pindel, varscan2
- FNDC3A | c.3344G>A p.R1115H (on ENST00000492622 / NM_001079673.2; = p.R1059H on NM_014923.5) | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs888268244; called by muse, mutect2
- FOSB | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 63/586 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV100798832, COSV62278693; called by muse, varscan2
- FOXD3 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 79/550 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV100942775; called by muse, mutect2, varscan2
- FPGS | c.528del p.Y177Tfs*5 | Frame Shift Del (DEL) | VAF 48/394 reads (12%) | catalogued as rs1201069294, COSV64675665; called by mutect2, pindel, varscan2
- FRMD4B | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 54/361 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs373596239; called by muse, mutect2, varscan2
- FSCN1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 79/724 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1179642651; called by muse, mutect2, varscan2
- FSD1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 61/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55695912; called by muse, mutect2, varscan2
- FSD2 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 64/638 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV100574985; called by muse, mutect2
- FSHR | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 62/483 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58638788; called by muse, mutect2, varscan2
- FSIP2 | c.5852C>T p.A1951V | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.691); catalogued as rs1255902853; called by muse, mutect2, varscan2
- FXYD4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs150156235, COSV72052652; called by muse, mutect2, varscan2
- FYB2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100599865; called by muse, mutect2, varscan2
- FZD10 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 74/670 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs765524304; called by muse, mutect2, varscan2
- GAB2 | c.1499G>A p.R500Q (on ENST00000361507 / NM_080491.3; = p.R462Q on NM_012296.3) | Missense Mutation (SNP) | VAF 65/509 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs370982595, COSV60867265; called by muse, mutect2, varscan2
- GABPB1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.955); catalogued as COSV55017287; called by muse, varscan2
- GABRA6 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772232018, COSV50888036; called by muse, mutect2, varscan2
- GABRG1 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 33/369 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs1193002288, COSV99778407; called by muse, mutect2
- GABRR1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781685308, COSV65618863; called by muse, mutect2, varscan2
- GATA2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 145/716 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); catalogued as rs769473824, COSV62003090; called by muse, mutect2, varscan2
- GCDH | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 81/551 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs773713507; called by muse, varscan2
- GDE1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 65/596 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs776485666; called by muse, mutect2, varscan2
- GFRA3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 74/616 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51228666; called by muse, mutect2, varscan2
- GIPC3 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT tolerated, low confidence (0.19); catalogued as rs1268583345; called by muse, mutect2, varscan2
- GLI3 | c.2873C>T p.A958V | Missense Mutation (SNP) | VAF 80/690 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373918769; called by muse, mutect2, varscan2
- GNAL | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 42/796 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1489407669; called by muse, mutect2
- GOLIM4 | c.1891del p.R631Gfs*87 | Frame Shift Del (DEL) | VAF 45/507 reads (9%) | catalogued as rs1210775698; called by mutect2, pindel
- GON4L | c.5669A>G p.H1890R | Missense Mutation (SNP) | VAF 49/402 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1191030084; called by muse, mutect2, varscan2
- GPN3 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 31/306 reads (10%) | catalogued as COSV57400608; called by muse, mutect2
- GPR149 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.187); catalogued as rs749204115, COSV67667215; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 22/218 reads (10%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.025); catalogued as rs752554782; called by muse, mutect2, varscan2
- GRIN2B | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.955); catalogued as rs748075089, COSV101663194, COSV74205288; called by muse, mutect2, varscan2
- GRINA | c.966C>T p.C322= | Splice Region (SNP) | VAF 67/366 reads (18%) | catalogued as rs1564258331; called by muse, mutect2, varscan2
- H2BC1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs149864212; called by muse, mutect2
- HAS3 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 79/591 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs374428400; called by muse, varscan2
- HCAR3 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs768138411, COSV63676750; called by muse, mutect2, varscan2
- HCN3 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 84/622 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs765937571, COSV64233784; called by muse, varscan2
- HDLBP | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60497065; called by muse, mutect2, varscan2
- HEBP2 | c.593dup p.N198Kfs*2 | Frame Shift Ins (INS) | VAF 27/246 reads (11%) | catalogued as rs769528102; called by mutect2, varscan2
- HECW1 | c.3125G>A p.R1042Q | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs531623127, COSV67842380; called by muse, mutect2
- HINT2 | c.78dup p.Q27Afs*10 | Frame Shift Ins (INS) | VAF 55/504 reads (11%) | catalogued as rs768013756; called by mutect2, pindel, varscan2
- HIPK2 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100702382; called by muse, mutect2, varscan2
- HIVEP3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1376638578, COSV56019729; called by muse, mutect2, varscan2
- HNRNPCL1 | c.610dup p.I204Nfs*2 | Frame Shift Ins (INS) | VAF 74/542 reads (14%) | catalogued as rs780901996; called by mutect2, varscan2
- HRNR | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 46/483 reads (10%) | catalogued as rs1242137481; called by muse, mutect2, varscan2
- HTRA3 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 54/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs142390648; called by muse, mutect2
- IARS1 | c.709T>A p.C237S | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100986774; called by muse, mutect2
- IBA57 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 72/631 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs761100484, COSV100812778; called by muse, mutect2, varscan2
- ICA1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as rs778660693, COSV55579052; called by muse, mutect2, varscan2
- ICAM5 | c.2518G>A p.V840M | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as rs968994125; called by muse, mutect2, varscan2
- IFFO2 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1417029658; called by muse, mutect2
- IFT140 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 66/506 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147756729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV1-58 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs370108530; called by muse, mutect2, varscan2
- IGSF21 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as rs371692339; called by muse, mutect2
- IL17RA | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 77/638 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs762369642, COSV60052947; called by muse, mutect2
- IPO5 | c.3176A>G p.K1059R | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV55155023; called by muse, mutect2, varscan2
- IPO7 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63352605; called by muse, varscan2
- IPP | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as rs749635644; called by muse, mutect2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 32/228 reads (14%) | catalogued as rs759821884; called by mutect2, varscan2
- IRX4 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 92/726 reads (13%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.968); catalogued as rs1051839459; called by muse, varscan2
- ITCH | c.2399G>A p.R800H (on ENST00000262650 / NM_001257137.3; = p.R759H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs759593203, COSV52931952, COSV52933921; called by muse, mutect2, varscan2
- ITGA7 | c.3457C>T p.R1153W (on ENST00000555728; = p.R1109W on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/646 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs117803261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAM | c.2054G>A p.R685H (on ENST00000648685 / NM_001145808.2; = p.R684H on NM_000632.4) | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1237341647, COSV54941294; called by muse, mutect2, varscan2
- ITPA | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs556565777; called by muse, mutect2, varscan2
- ITPKA | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs775913660; called by muse, mutect2, varscan2
- KANSL3 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs976557866; called by muse, mutect2, varscan2
- KBTBD12 | c.1835del p.P612Rfs*78 | Frame Shift Del (DEL) | VAF 32/364 reads (9%) | catalogued as rs1187501286, COSV100675484; called by mutect2, pindel
- KCNA1 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101230126; called by muse, mutect2, varscan2
- KCNA6 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV54976250, COSV54978325; called by muse, mutect2, varscan2
- KCNC2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 84/670 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as rs1209434610, COSV54363607; called by muse, mutect2, varscan2
- KCNG3 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as rs375643888, COSV100044889; called by muse, mutect2, varscan2
- KCNJ3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 40/471 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54539001, COSV99716261; called by muse, mutect2
- KCNK18 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100571966; called by muse, mutect2, varscan2
- KCNK3 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 71/615 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as rs1341257541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5A | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs779176655, COSV66992702; called by muse, mutect2, varscan2
- KEAP1 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 56/437 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261404; called by muse, mutect2, varscan2
- KIAA1191 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs377317335; called by muse, mutect2, varscan2
- KIF22 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193698884; called by muse, mutect2, varscan2
- KIF2C | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.774); catalogued as rs200680875, COSV64763904; called by muse, mutect2, varscan2
- KIF6 | c.1410G>C p.Q470H | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs776739035; called by muse, mutect2, varscan2
- KLF5 | c.1163_1165del p.S388_H389delinsY | In Frame Del (DEL) | VAF 33/244 reads (14%) | catalogued as COSV66615349; called by pindel, varscan2
- KMT2D | c.14924G>A p.R4975H | Missense Mutation (SNP) | VAF 74/552 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs757011865; called by muse, mutect2, varscan2
- KRT1 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 92/660 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs766766361, COSV52865164; called by muse, mutect2, varscan2
- KRT26 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372502675, COSV56970677, COSV56973714; called by muse, mutect2, varscan2
- KRT71 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 56/472 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.589); catalogued as rs1292267951, COSV57289252; called by muse, mutect2, varscan2
- KRTAP10-4 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 87/762 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs782456498; called by muse, mutect2, varscan2
- KRTAP4-16 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.82); catalogued as rs1363684568; called by muse, mutect2, varscan2
- KRTAP8-1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1157284010, COSV61597926; called by muse, mutect2, varscan2
- LAMA5 | c.9349G>A p.A3117T | Missense Mutation (SNP) | VAF 74/524 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs372181940; called by muse, mutect2, varscan2
- LAMB2 | c.5080C>T p.R1694C | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs779790990, COSV100026162, COSV100026223; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 30/258 reads (12%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS2 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 76/662 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1318253418; called by muse, mutect2, varscan2
- LCAT | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 56/525 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1221945564, COSV50452035; called by muse, mutect2, varscan2
- LCOR | c.4658G>A p.R1553Q | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300739948; called by muse, mutect2, varscan2
- LHPP | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 51/385 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs1281389112; called by muse, mutect2, varscan2
- LIME1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 64/564 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.246); catalogued as COSV56651208; called by muse, mutect2, varscan2
- LMAN1L | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs1165704643, COSV59001566; called by muse, mutect2, varscan2
- LOXHD1 | c.6562C>T p.R2188W (on ENST00000642948; = p.R2126W on NM_144612.7) | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771007568, COSV56059805; called by muse, mutect2, varscan2
- LRIG3 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV100292712; called by muse, mutect2
- LRP4 | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs1389594811; called by muse, mutect2
- LRRC34 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57185998; called by muse, mutect2, varscan2
- LRRC4 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 62/558 reads (11%) | catalogued as COSV99975123; called by muse, mutect2, varscan2
- LRRIQ3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs571959184, COSV63041006; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 46/310 reads (15%) | catalogued as rs756089224; called by mutect2, varscan2
- LSM14B | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs780178759; called by muse, mutect2, varscan2
- LSP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs772024277; called by muse, mutect2, varscan2
- LZTS3 | c.1631G>A p.R544H (on ENST00000329152; = p.R498H on NM_001282533.2) | Missense Mutation (SNP) | VAF 84/539 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1232217132; called by muse, varscan2
- MAB21L2 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 51/449 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58261452; called by muse, mutect2, varscan2
- MAFA | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs774483749; called by muse, mutect2, varscan2
- MAGEC3 | c.502del p.E168Rfs*45 | Frame Shift Del (DEL) | VAF 47/414 reads (11%) | catalogued as rs1295601131; called by mutect2, pindel
- MAGEC3 | c.1395G>C p.Q465H | Missense Mutation (SNP) | VAF 80/613 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV100024937, COSV100025570; called by muse, mutect2, varscan2
- MAGED1 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 90/725 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as rs782201149; called by muse, mutect2, varscan2
- MAGED1 | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 48/461 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV58515350; called by muse, mutect2
- MALT1 | c.374dup p.G126Rfs*40 | Frame Shift Ins (INS) | VAF 32/284 reads (11%) | catalogued as rs1450997592; called by mutect2, pindel, varscan2
- MAP1S | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 89/636 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.912); catalogued as rs769908510; called by muse, mutect2, varscan2
- MAP2 | c.4553G>A p.S1518N | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs745598144; called by muse, mutect2
- MAP2K7 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67607630; called by muse, mutect2, varscan2
- MC5R | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 80/614 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs781640318, COSV61254157; called by muse, mutect2, varscan2
- MCM2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as rs756507591, COSV54036111; called by muse, mutect2, varscan2
- MDGA2 | c.1361G>A p.R454Q (on ENST00000399232 / NM_001113498.2; = p.R156Q on NM_182830.4) | Missense Mutation (SNP) | VAF 47/406 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771715302, COSV62115855; called by muse, varscan2
- MFAP5 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs765205871, COSV100848183, COSV63945013; called by muse, mutect2, varscan2
- MICALL1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 81/613 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs142515624; called by muse, mutect2, varscan2
- MIDEAS | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 58/472 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs773067122, COSV54096625; called by muse, mutect2, varscan2
- MLNR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 75/622 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.413); catalogued as rs1035460490; called by muse, mutect2, varscan2
- MMD2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780813727, COSV101287097; called by muse, mutect2, varscan2
- MME | c.536-1G>T p.X179_splice | Splice Site (SNP) | VAF 25/256 reads (10%) | catalogued as rs759072209; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 30/214 reads (14%) | catalogued as rs755830405; called by mutect2, varscan2
- MOCS1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772989676, COSV100418823, COSV57934678; called by muse, mutect2
- MORN1 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 64/496 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs369325745; called by muse, varscan2
- MPP2 | c.1450G>A p.E484K (on ENST00000461854 / NM_001278372.2; = p.E460K on NM_005374.5) | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762561901, COSV52237986; called by muse, mutect2, varscan2
- MPP2 | c.533C>T p.T178M (on ENST00000461854 / NM_001278372.2; = p.T154M on NM_005374.5) | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779453977, COSV52238854, COSV52240628; called by muse, mutect2, varscan2
- MRPL27 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs142736439; called by muse, mutect2, varscan2
- MRPS18B | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 64/548 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs144768627; called by muse, mutect2, varscan2
- MRPS7 | c.726G>A p.W242* | Nonsense Mutation (SNP) | VAF 20/296 reads (7%) | catalogued as rs745556197; called by muse, mutect2
- MSL3 | c.1562A>G p.Y521C (on ENST00000312196 / NM_078629.4; = p.Y355C on NM_006800.4) | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs752067112; called by muse, varscan2
- MTHFR | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 43/488 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs977038830, CM088302, COSV64877643; called by muse, mutect2
- MUC12 | c.9898G>A p.V3300I (on ENST00000379442; = p.V3157I on NM_001164462.1) | Missense Mutation (SNP) | VAF 178/3736 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs758247435; called by muse, mutect2
- MUC16 | c.40610G>T p.R13537M | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV66693914; called by muse, mutect2
- MUC4 | c.14834C>T p.A4945V (on ENST00000463781 / NM_018406.7; = p.A709V on NM_004532.6) | Missense Mutation (SNP) | VAF 65/540 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs757658061; called by muse, mutect2, varscan2
- MXD3 | c.148dup p.Q50Pfs*15 | Frame Shift Ins (INS) | VAF 44/351 reads (13%) | catalogued as rs866699857; called by mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 54/503 reads (11%) | catalogued as rs764857791; called by mutect2, varscan2
- MYBPC3 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs753884765, COSV57030338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBP2 | c.1300A>T p.I434L (on ENST00000357337; = p.I472L on NM_015057.5) | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1056750004; called by muse, mutect2
- MYH3 | c.1002C>T p.D334= | Splice Region (SNP) | VAF 28/262 reads (11%) | catalogued as rs764425505; called by muse, mutect2, varscan2
- MYO18B | c.7177G>A p.D2393N | Missense Mutation (SNP) | VAF 57/490 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs751707031, COSV59137434; called by muse, mutect2, varscan2
- MYO19 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 101/625 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs758725620; called by muse, mutect2, varscan2
- MYO1B | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771551697, COSV100270324; called by muse, varscan2
- MYO7A | c.6089C>T p.T2030M | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs768874284, COSV68685070; called by muse, mutect2, varscan2
- MYPOP | c.1139dup p.H381Tfs*69 | Frame Shift Ins (INS) | VAF 46/330 reads (14%) | catalogued as rs757587344; called by mutect2, varscan2
- MYRF | c.2132G>A p.R711Q (on ENST00000278836 / NM_001127392.3; = p.R702Q on NM_013279.4) | Missense Mutation (SNP) | VAF 68/560 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1441208457; called by muse, mutect2, varscan2
- MYRFL | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 38/353 reads (11%) | catalogued as rs1429212771; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 40/296 reads (14%) | catalogued as rs763376147; called by mutect2, varscan2
- NBEA | c.3809G>A p.G1270D | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.457); catalogued as rs530242552; called by muse, mutect2, varscan2
- NBEAL2 | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 91/681 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as rs775952133; called by muse, mutect2, varscan2
- NCOR2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867064743; called by muse, mutect2, varscan2
- NHS | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 82/641 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1305600869; called by muse, mutect2, varscan2
- NID1 | c.2695G>A p.V899M | Missense Mutation (SNP) | VAF 62/608 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs748671846, COSV51617969; called by muse, varscan2
- NINJ2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs555731031; called by muse, mutect2, varscan2
- NLGN2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs751955059; called by muse, mutect2, varscan2
- NLRP2 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 71/595 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753846462; called by muse, mutect2, varscan2
- NLRP4 | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs775042848, COSV56707454; called by muse, mutect2, varscan2
- NOL6 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs762753971; called by muse, mutect2, varscan2
- NOS3 | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 96/495 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1029528279; called by muse, mutect2, varscan2
- NOTCH3 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 55/359 reads (15%) | catalogued as rs1284132838, COSV54646925; called by muse, mutect2, varscan2
- NRCAM | c.3716G>A p.R1239Q (on ENST00000379028 / NM_001371124.1; = p.R1118Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/449 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.047); catalogued as rs753564364, COSV61048115; called by muse, mutect2, varscan2
- NRCAM | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs757035974, COSV100694550, COSV100695833; called by muse, mutect2, varscan2
- NRDC | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1415944883, COSV61402345; called by muse, mutect2, varscan2
- NRDE2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs760733906, COSV62962974; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | catalogued as rs1167519601; called by mutect2, pindel
- NSD2 | c.1576del p.R526Efs*72 | Frame Shift Del (DEL) | VAF 38/269 reads (14%) | catalogued as rs1445291234; called by mutect2, pindel, varscan2
- NTN1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 69/539 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as rs768189573; called by muse, mutect2, varscan2
- NUBP1 | c.833A>G p.D278G | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51594531; called by muse, varscan2
- NUDT18 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1043832914; called by muse, mutect2, varscan2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 39/315 reads (12%) | catalogued as rs1566064574; called by mutect2, pindel, varscan2
- NUP133 | c.3219C>G p.I1073M | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54576134; called by muse, mutect2
- NUPR2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 131/649 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs981316922; called by muse, mutect2, varscan2
- NUSAP1 | c.524dup p.N175Kfs*2 | Frame Shift Ins (INS) | VAF 38/289 reads (13%) | catalogued as rs775467155; called by mutect2, pindel, varscan2
- NWD2 | c.3587A>G p.E1196G | Missense Mutation (SNP) | VAF 43/491 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1191392845; called by muse, mutect2
- NYAP1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 76/592 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1185201934; called by muse, mutect2, varscan2
- OBP2A | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs139660402; called by muse, mutect2
- OLFM1 | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 81/571 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs1276900616; called by muse, mutect2, varscan2
- OLFML3 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 48/368 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs375036310; called by muse, mutect2, varscan2
- OR10H1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 68/855 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs143282709, COSV58470784; called by muse, mutect2
- OR10J3 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.689); catalogued as COSV59954725; called by muse, mutect2, varscan2
- OR10J3 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1415806741; called by muse, mutect2, varscan2
- OR11H4 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs753438056, COSV100197559; called by muse, mutect2, varscan2
- OR14A16 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100713669, COSV62927614; called by muse, mutect2
- OR14K1 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs544886174, COSV99315527; called by muse, mutect2, varscan2
- OR2A12 | c.783del p.K262Sfs*23 | Frame Shift Del (DEL) | VAF 43/475 reads (9%) | catalogued as rs1244484998; called by mutect2, pindel
- OR4N2 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 40/1298 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.042); catalogued as COSV60051614; called by muse, mutect2
- OR51E1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481229144; called by muse, mutect2, varscan2
- OR5B12 | c.589_590del p.I197Ffs*8 | Frame Shift Del (DEL) | VAF 48/359 reads (13%) | catalogued as rs776684579; called by mutect2, varscan2
- OR5M10 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 59/487 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101595919; called by muse, mutect2, varscan2
- OR8K3 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 47/519 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs905125363, COSV100449700, COSV57132293; called by muse, mutect2
- OR9K2 | c.466C>T p.L156F (on ENST00000305377; = p.L134F on NM_001005243.1) | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100543899; called by muse, mutect2, varscan2
- OSBPL2 | c.1337C>T p.T446M (on ENST00000313733 / NM_144498.4; = p.T434M on NM_014835.4) | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs1291158471, COSV100569115; called by muse, mutect2
- OTOF | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 37/434 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.635); catalogued as rs754009907, COSV99716396; ClinVar: uncertain significance; called by muse, mutect2
- OXCT2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59594184; called by muse, mutect2, varscan2
- OXER1 | c.231dup p.S78Vfs*61 | Frame Shift Ins (INS) | VAF 86/573 reads (15%) | catalogued as rs753912794; called by mutect2, varscan2
- OXSR1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs762812182; called by muse, mutect2, varscan2
- PALM3 | c.52C>T p.R18W (on ENST00000340790; = p.R33W on NM_001145028.2) | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374025379, COSV54600951; called by muse, mutect2, varscan2
- PAM | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs746515192, COSV57215372; called by muse, mutect2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 30/236 reads (13%) | catalogued as rs747970462, COSV62809272; called by pindel, varscan2
- PAQR9 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 73/616 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV100503739; called by muse, mutect2, varscan2
- PARD3 | c.2533G>A p.V845I | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs745426397, COSV60764889, COSV60765070; called by muse, mutect2, varscan2
- PARD3B | c.3466C>T p.R1156* (on ENST00000406610 / NM_001302769.2; = p.R1087* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 66/570 reads (12%) | catalogued as rs776213727, COSV100594116; called by muse, mutect2
- PAXIP1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68184797; called by muse, mutect2, varscan2
- PBRM1 | c.4288G>T p.E1430* (on ENST00000296302 / NM_001366071.2; = p.G1378C on NM_018313.5) | Nonsense Mutation (SNP) | VAF 28/237 reads (12%) | catalogued as COSV56261090; called by muse, mutect2, varscan2
- PCDHA1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 57/576 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.413); catalogued as rs1554117874, COSV65376238; called by muse, mutect2, varscan2
- PCDHAC1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 49/458 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781857799, COSV53846278; called by muse, mutect2, varscan2
- PCDHGA11 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 38/444 reads (9%) | catalogued as rs750692137, COSV53907247; called by muse, mutect2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 70/554 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, varscan2
- PCNX3 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs534158679; called by muse, mutect2, varscan2
- PDE3A | c.3020A>G p.H1007R | Missense Mutation (SNP) | VAF 58/472 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62983715; called by muse, mutect2, varscan2
- PDZD7 | c.2220del p.V741Wfs*12 | Frame Shift Del (DEL) | VAF 36/338 reads (11%) | catalogued as rs1211492964; called by mutect2, varscan2
- PENK | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 70/556 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV59240781; called by muse, mutect2, varscan2
- PEX14 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 88/635 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1375168634, COSV100750380; called by muse, varscan2
- PGAP2 | c.263G>A p.R88H (on ENST00000463452 / NM_001346398.2; = p.R149H on NM_014489.4) | Missense Mutation (SNP) | VAF 78/564 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53466853; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 35/280 reads (13%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PIGZ | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 127/655 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs147518119; called by muse, mutect2, varscan2
- PITPNM2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758304; called by muse, mutect2, varscan2
- PKHD1L1 | c.6850C>T p.R2284W | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201214727; called by muse, mutect2, varscan2
- PLCH1 | c.2023G>A p.A675T (on ENST00000340059 / NM_001130960.2; = p.A687T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs753532293, COSV58209841; called by muse, mutect2, varscan2
- PLD2 | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 45/356 reads (13%) | catalogued as rs756151080, COSV54009293; called by muse, mutect2, varscan2
- PLEC | c.2390C>T p.A797V (on ENST00000322810 / NM_201380.4; = p.A687V on NM_000445.5) | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs782079821, COSV59620392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs201461876; called by muse, mutect2, varscan2
- PLXNA3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 59/633 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs782557318, COSV63754826; called by muse, mutect2
- PLXND1 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 99/462 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs778790008; called by muse, mutect2, varscan2
- POLD1 | c.537del p.R180Gfs*3 | Frame Shift Del (DEL) | VAF 58/545 reads (11%) | catalogued as COSV70957044; called by mutect2, pindel, varscan2
- POLR2E | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 55/389 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs779847415; called by muse, mutect2, varscan2
- POLR3D | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.154); catalogued as rs766476082; called by muse, mutect2, varscan2
- PPFIA1 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771724048, COSV54134949; called by muse, mutect2, varscan2
- PPM1N | c.281del p.P94Rfs*52 | Frame Shift Del (DEL) | VAF 77/641 reads (12%) | catalogued as rs1490629906; called by mutect2, pindel, varscan2
- PPP1R1B | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780007110; called by muse, mutect2
- PPP1R3C | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs377306002; called by muse, mutect2, varscan2
- PPP1R3F | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 109/811 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99279120; called by muse, mutect2, varscan2
- PPP6R1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1011277098, COSV69799686; called by muse, mutect2, varscan2
- PRKAR1B | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 108/477 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.227); catalogued as rs978367242; called by muse, mutect2, varscan2
- PROB1 | c.193del p.A65Rfs*107 | Frame Shift Del (DEL) | VAF 100/598 reads (17%) | catalogued as rs1424842964; called by mutect2, pindel, varscan2
- PROC | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 60/488 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs375912553, CM071938, CM144436; called by muse, varscan2
- PRR14 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 72/578 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs139644175; called by muse, mutect2, varscan2
- PRR18 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 87/618 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs751695297; called by muse, mutect2, varscan2
- PRR23C | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 62/573 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as rs770756308, COSV68827256; called by muse, mutect2, varscan2
- PRR32 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 60/700 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV64420990; called by muse, mutect2
- PSG5 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1326579387; called by muse, varscan2
- PTGES | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481939974; called by muse, mutect2
- PTPRO | c.1022del p.F341Sfs*5 | Frame Shift Del (DEL) | VAF 49/392 reads (13%) | catalogued as COSV55523719; called by mutect2, pindel, varscan2
- PTPRU | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 55/437 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375192977; called by muse, mutect2, varscan2
- PXN | c.978dup p.P327Afs*18 (on ENST00000228307 / NM_001080855.3; = p.P293Afs*18 on NM_002859.4) | Frame Shift Ins (INS) | VAF 63/652 reads (10%) | catalogued as rs1239277803; called by mutect2, pindel, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 31/218 reads (14%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB34 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 44/337 reads (13%) | catalogued as rs139219728; called by muse, mutect2, varscan2
- RAD52 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 65/484 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758444228, COSV57272810; called by muse, mutect2, varscan2
- RAD9A | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs1436791221; called by muse, mutect2, varscan2
- RADIL | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 118/572 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377167416; called by muse, mutect2, varscan2
- RANBP17 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1446767000; called by muse, mutect2, varscan2
- RAP1GAP | c.1045dup p.L349Pfs*12 | Frame Shift Ins (INS) | VAF 46/422 reads (11%) | catalogued as rs753793537; called by mutect2, varscan2
- RASSF8 | c.429del p.F143Lfs*14 | Frame Shift Del (DEL) | VAF 35/329 reads (11%) | catalogued as rs34200188; called by mutect2, pindel, varscan2
- RBM14 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 55/467 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV59557741; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 28/200 reads (14%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as rs773121331, COSV56481392; called by muse, mutect2, varscan2
- RCN2 | c.684A>G p.I228M | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1251999791; called by muse, mutect2, varscan2
- RELN | c.9673G>A p.V3225M | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs755369509; ClinVar: uncertain significance; called by muse, mutect2
- RFTN1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775324927, COSV100490010, COSV61918145; called by muse, mutect2
- RFX1 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 80/570 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.336); catalogued as rs897581651; called by muse, mutect2, varscan2
- RGS12 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776126809; called by muse, mutect2, varscan2
- RHPN2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs766609551, COSV54280624; called by muse, mutect2
- RIPK1 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52531965; called by muse, mutect2, varscan2
- RMC1 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 29/319 reads (9%) | catalogued as rs866254778, COSV52574905; called by muse, mutect2
- RNF19A | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 51/465 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.652); catalogued as rs768668517, COSV61992555; called by muse, mutect2, varscan2
- RNF223 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 88/632 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.223); catalogued as rs1159537437, COSV69251270; called by muse, varscan2
- RNF225 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 73/557 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1394477284; called by muse, mutect2, varscan2
- RNF31 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 67/524 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1163489688; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 134/628 reads (21%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF44 | c.577del p.Q193Sfs*80 | Frame Shift Del (DEL) | VAF 50/319 reads (16%) | catalogued as rs748776013; called by mutect2, pindel, varscan2
- ROBO2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59927745; called by muse, mutect2, varscan2
- ROBO4 | c.1503A>G p.P501= | Splice Region (SNP) | VAF 56/438 reads (13%) | catalogued as rs766781525; called by muse, mutect2, varscan2
- RP1 | c.3314G>A p.G1105D | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.341); catalogued as rs973221981; called by muse, mutect2, varscan2
- RPGRIP1 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV52844593; called by muse, mutect2, varscan2
- RRAD | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 45/638 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1468162427, COSV55337017; called by muse, mutect2
- RRAS | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs757080959, COSV55868605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RS1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs141077105; called by muse, mutect2
- RSPO1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.083); catalogued as rs763148695, COSV100740681; called by muse, mutect2, varscan2
- RTN3 | c.3089dup p.A1031Gfs*28 (on ENST00000377819 / NM_001265589.2; = p.A235Gfs*28 on NM_006054.4) | Frame Shift Ins (INS) | VAF 34/260 reads (13%) | catalogued as rs747510098; called by mutect2, varscan2
- RTP5 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 94/762 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs745937449, COSV58322175; called by muse, mutect2, varscan2
- RUBCNL | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs768684570, COSV59793800; called by muse, mutect2
- RYR2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.945); catalogued as rs1036926941, COSV63667488, COSV63684165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SASH1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1050414808, COSV66559930; called by muse, mutect2, varscan2
- SASH3 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 54/562 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759348769, COSV63556644; called by muse, mutect2
- SBF1 | c.1632del p.M545* | Frame Shift Del (DEL) | VAF 42/356 reads (12%) | catalogued as COSV62365952; called by mutect2, pindel, varscan2
- SCNN1B | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 74/673 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140945152; ClinVar: uncertain significance / benign; called by muse, varscan2
- SCUBE2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs72549241, COSV58541540; called by muse, mutect2, varscan2
- SDC1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 79/566 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as rs145702352; called by muse, mutect2, varscan2
- SDF4 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55420845; called by muse, mutect2, varscan2
- SDK1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs755048901, COSV67378774; called by muse, varscan2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 49/456 reads (11%) | catalogued as COSV64602454; called by pindel, varscan2*
- SEL1L2 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.877); catalogued as rs139504161, COSV53152213; called by muse, mutect2, varscan2
- SELE | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773134869, COSV60978200; called by muse, mutect2, varscan2
- SEMA4A | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 67/578 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.424); catalogued as rs779154677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766020101; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 38/288 reads (13%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINA11 | c.108del p.R37Gfs*42 | Frame Shift Del (DEL) | VAF 64/517 reads (12%) | catalogued as rs779299403; called by pindel, varscan2
- SERPINB12 | c.449del p.N150Tfs*39 | Frame Shift Del (DEL) | VAF 50/384 reads (13%) | catalogued as rs760486497; called by mutect2, pindel, varscan2
- SERTAD2 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 73/643 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as rs146983633; called by muse, mutect2, varscan2
- SERTM2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 31/361 reads (9%) | PolyPhen benign (0); catalogued as rs1445985439; called by muse, mutect2
- SFI1 | c.2630C>T p.A877V (on ENST00000400288 / NM_001007467.3; = p.A846V on NM_014775.4) | Missense Mutation (SNP) | VAF 63/576 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756654178, COSV63475773; called by muse, mutect2, varscan2
- SFRP5 | c.682_684del p.K228del | In Frame Del (DEL) | VAF 62/438 reads (14%) | catalogued as rs757855988; called by pindel, varscan2
- SFT2D3 | c.242_248del p.G81Afs*11 | Frame Shift Del (DEL) | VAF 72/649 reads (11%) | catalogued as rs748029693; called by mutect2, pindel, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/190 reads (12%) | catalogued as rs772386209; called by mutect2, varscan2
- SGTB | c.684G>A p.A228= | Splice Region (SNP) | VAF 38/258 reads (15%) | catalogued as rs563437922; called by muse, varscan2
- SH3PXD2A | c.989G>A p.R330Q (on ENST00000369774 / NM_001365079.1; = p.R302Q on NM_014631.2) | Missense Mutation (SNP) | VAF 67/538 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as rs201054626, COSV60117449; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 41/367 reads (11%) | catalogued as rs774210627; called by mutect2, pindel, varscan2
- SIDT2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs201739720; called by muse, mutect2, varscan2
- SIGLEC7 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs140841032, COSV58317452; called by muse, varscan2
- SIPA1L2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs1167028057; called by muse, mutect2, varscan2
- SIPA1L3 | c.4220C>T p.S1407L | Missense Mutation (SNP) | VAF 33/360 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs866641225, COSV55918628; called by muse, mutect2
- SKI | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141961299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A4 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762940661, COSV57932774; called by muse, mutect2
- SLC14A2 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs766518249, COSV54915739; called by muse, mutect2, varscan2
- SLC27A1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 61/400 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1568424613, COSV53095531; called by muse, mutect2, varscan2
- SLC29A4 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs774334196; called by muse, mutect2, varscan2
- SLC30A6 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs371890282; called by muse, mutect2
- SLC35E2B | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 31/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748379935, COSV52361858; called by muse, mutect2, varscan2
- SLC38A7 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 33/593 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs377080241; called by muse, mutect2
- SLC46A2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 59/517 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1161198149, COSV100953488; called by muse, varscan2
- SLC49A4 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs537988432, COSV99659270; called by muse, mutect2
- SLITRK1 | c.134dup p.F47Lfs*30 | Frame Shift Ins (INS) | VAF 44/338 reads (13%) | catalogued as rs763682501; called by mutect2, varscan2
- SMARCAL1 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs760511139; called by muse, mutect2, varscan2
- SMG1 | c.7379G>A p.R2460H | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs749472681; called by muse, mutect2, varscan2
- SNAPIN | c.392del p.P131Lfs*9 | Frame Shift Del (DEL) | VAF 34/290 reads (12%) | catalogued as rs1278771008; called by pindel, varscan2
- SOAT2 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs747295597, COSV100037138; called by muse, varscan2
- SOBP | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs1231573103; called by muse, mutect2, varscan2
- SORCS2 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 46/340 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs1005466427, COSV100212652; called by muse, varscan2
- SOWAHB | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs149260007; called by muse, mutect2, varscan2
- SOX10 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 66/563 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs767972523, COSV62807386; called by muse, mutect2, varscan2
- SOX8 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 88/670 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs768170508; called by muse, varscan2
- SP9 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV67602169; called by muse, mutect2, varscan2
- SPEG | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 95/759 reads (13%) | catalogued as rs1484291970; called by muse, mutect2, varscan2
- SPEG | c.9734A>G p.Q3245R | Missense Mutation (SNP) | VAF 79/599 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100405095; called by muse, mutect2, varscan2
- SPEN | c.5824G>A p.A1942T | Missense Mutation (SNP) | VAF 63/548 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV65363411; called by muse, mutect2, varscan2
- SPTBN1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359396975, COSV61690760, COSV61695678; called by muse, mutect2, varscan2
- SPTBN2 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 80/622 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as rs776861052, COSV59452746; called by muse, mutect2, varscan2
- SPTBN4 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 68/675 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1175959793; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 49/361 reads (14%) | catalogued as rs763130641; called by mutect2, pindel, varscan2
- SRP72 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1460929329; called by muse, mutect2, varscan2
- SRPK3 | c.1013_1014insG p.G339Rfs*5 | Frame Shift Ins (INS) | VAF 92/749 reads (12%) | catalogued as rs782415110, COSV54207595, COSV54209068; called by mutect2, pindel*
- SRRM4 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 62/401 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs374357852; called by muse, mutect2, varscan2
- STAP2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as rs1167385281, COSV74071008; called by muse, mutect2, varscan2
- STKLD1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 62/465 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs781798256; called by muse, mutect2, varscan2
- STRN4 | c.2257G>A p.V753I | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs751330774; called by muse, varscan2
- STX11 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 67/576 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV62448977; called by muse, mutect2, varscan2
- SUGCT | c.1255G>A p.D419N (on ENST00000335693 / NM_001193313.2; = p.D445N on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/542 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs769042792, COSV59337882; called by muse, mutect2, varscan2
- SUN1 | c.1790G>A p.R597Q (on ENST00000405266 / NM_001367651.1; = p.R477Q on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/585 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374707736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SURF4 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100915193; called by muse, mutect2
- SV2A | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as rs1559789757, COSV64964163; called by muse, mutect2
- SYCP1 | c.2288T>C p.V763A | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs749571601; called by muse, mutect2, varscan2
- SYMPK | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs1023200427, COSV55610488; called by muse, mutect2, varscan2
- SYNE1 | c.25159G>A p.V8387M (on ENST00000367255 / NM_182961.4; = p.V8339M on NM_033071.3) | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs119103247, CM075028, COSV99553542; called by muse, mutect2
- SYNE1 | c.3815A>G p.Q1272R (on ENST00000367255 / NM_182961.4; = p.Q1279R on NM_033071.3) | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV54959167; called by muse, mutect2, varscan2
- SYT15 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as rs201664076; called by muse, mutect2
- TACC2 | c.8641G>A p.A2881T (on ENST00000334433; = p.A959T on NM_006997.4) | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104393599; called by muse, mutect2
- TAF1 | c.3800C>T p.A1267V (on ENST00000373790 / NM_138923.4; = p.A1288V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/468 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1475300074, COSV52115620, COSV52119736; called by muse, mutect2, varscan2
- TAF4 | c.1303del p.R435Afs*32 | Frame Shift Del (DEL) | VAF 76/611 reads (12%) | catalogued as rs1555879115; called by mutect2, varscan2
- TANC1 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs747252852, COSV55085330; called by muse, mutect2, varscan2
- TASOR | c.2290G>A p.G764S (on ENST00000355628 / NM_001365636.2; = p.G368S on NM_015224.3) | Missense Mutation (SNP) | VAF 52/445 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs1272712821; called by muse, mutect2, varscan2
- TBC1D4 | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 54/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100884591; called by muse, mutect2, varscan2
- TBXA2R | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 90/615 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as rs563919263; called by muse, mutect2, varscan2
- TCF12 | c.546dup p.V183Sfs*21 | Frame Shift Ins (INS) | VAF 32/260 reads (12%) | catalogued as rs1352708150; called by mutect2, varscan2
- TCF7L1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 44/562 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558661922, COSV56398531; called by muse, mutect2
- TENM1 | c.2821C>T p.R941* | Nonsense Mutation (SNP) | VAF 56/507 reads (11%) | catalogued as rs780679877, COSV100949909; called by muse, mutect2, varscan2
- TENM2 | c.6919C>T p.R2307W (on ENST00000518659 / NM_001122679.2; = p.R2068W on NM_001080428.3) | Missense Mutation (SNP) | VAF 66/549 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69124242; called by muse, mutect2, varscan2
- TENM3 | c.2082dup p.T695Dfs*5 | Frame Shift Ins (INS) | VAF 40/354 reads (11%) | catalogued as rs758217137; called by mutect2, varscan2
- TENM4 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as COSV53677064; called by muse, mutect2, varscan2
- TEP1 | c.7030G>A p.E2344K | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1480060166; called by muse, mutect2
- TERF2 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374494764; called by muse, mutect2, varscan2
- TFAP2B | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV99540864; called by muse, mutect2
- TFAP2E | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 69/568 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769390369; called by muse, mutect2, varscan2
- TG | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.548); catalogued as rs145085612; called by muse, mutect2, varscan2
- TGS1 | c.1552T>A p.F518I | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV52703606; called by muse, mutect2
- THBS3 | c.2745del p.R916Vfs*12 | Frame Shift Del (DEL) | VAF 70/526 reads (13%) | catalogued as rs1355720789; called by mutect2, pindel, varscan2
- THEGL | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 51/462 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs966580533; called by muse, mutect2, varscan2
- THSD7B | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 69/486 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55689607; called by muse, mutect2, varscan2
- TLX3 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 57/536 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99740672; called by muse, mutect2, varscan2
- TMEM161A | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV99365542; called by muse, mutect2, varscan2
- TMEM164 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 68/523 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1457996767, COSV99911278; called by muse, mutect2, varscan2
- TMPPE | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 63/493 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs777064398; called by muse, mutect2, varscan2
- TNIP2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 52/477 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs539733626, COSV59570304; called by muse, mutect2, varscan2
- TNPO2 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164109661, COSV100790349; called by muse, mutect2, varscan2
- TNRC6B | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 57/479 reads (12%) | catalogued as COSV57299500; called by muse, mutect2, varscan2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 23/196 reads (12%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TPK1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.704); catalogued as rs368467309; called by muse, mutect2
- TPR | c.6332G>A p.R2111H | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1044298886; called by muse, mutect2, varscan2
- TPR | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 51/441 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs780188815; called by muse, mutect2, varscan2
- TPRN | c.1610T>A p.L537H | Missense Mutation (SNP) | VAF 73/524 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV58806400, COSV58807402; called by muse, mutect2, varscan2
- TRAF7 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 58/479 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1371296824; called by muse, mutect2, varscan2
- TRAV8-4 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs555406044; called by muse, mutect2, varscan2
- TRIM31 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 88/760 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.137); catalogued as rs1562031339; called by muse, mutect2, varscan2
- TRIM32 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs552938001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM45 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 64/524 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs776584624, COSV56712967; called by muse, mutect2, varscan2
- TRIM51 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs774869203, COSV55263391; called by muse, mutect2
- TRIM55 | c.999A>T p.E333D | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1168265051, COSV52544131; called by mutect2, varscan2
- TRIM72 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 94/650 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as rs1194249329; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 23/171 reads (13%) | catalogued as rs780358338; called by mutect2, varscan2
- TRO | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 64/549 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs748992156, COSV51499283; called by muse, mutect2, varscan2
- TRO | c.3583A>G p.T1195A | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.063); catalogued as COSV99437227; called by muse, mutect2, varscan2
- TRPM1 | c.4119dup p.E1374Rfs*10 | Frame Shift Ins (INS) | VAF 58/464 reads (13%) | catalogued as rs1566981866; called by mutect2, pindel, varscan2
- TRPM6 | c.3460G>A p.V1154M | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs371962660; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 46/463 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs750791558, COSV54648478; called by muse, mutect2, varscan2
- TTC22 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 70/620 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs1323978356; called by muse, mutect2, varscan2
- TTC24 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs888192139; called by muse, mutect2, varscan2
- TTC26 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 42/327 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1475351206; called by muse, mutect2, varscan2
- TTN | c.94859G>A p.R31620H (on ENST00000591111; = p.R24196H on NM_003319.4) | Missense Mutation (SNP) | VAF 40/347 reads (12%) | PolyPhen benign (0.003); catalogued as rs373473754; called by muse, mutect2, varscan2
- TTN | c.94537C>T p.R31513C (on ENST00000591111; = p.R24089C on NM_003319.4) | Missense Mutation (SNP) | VAF 51/596 reads (9%) | PolyPhen probably damaging (0.998); catalogued as rs143556947; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.48781C>T p.R16261W (on ENST00000591111; = p.R8837W on NM_003319.4) | Missense Mutation (SNP) | VAF 26/349 reads (7%) | PolyPhen possibly damaging (0.736); catalogued as rs748647255, COSV100611969, COSV60389034; called by muse, mutect2
- TTN | c.36418C>T p.R12140C (on ENST00000591111; = p.R4716C on NM_003319.4) | Missense Mutation (SNP) | VAF 27/292 reads (9%) | PolyPhen possibly damaging (0.736); catalogued as rs768469221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP6 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 65/463 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.371); catalogued as rs373896485, COSV50583538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 49/588 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs376663677; called by muse, mutect2
- UFL1 | c.1978del p.R660Gfs*17 | Frame Shift Del (DEL) | VAF 26/237 reads (11%) | catalogued as rs750472217; called by mutect2, pindel, varscan2
- UPB1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753638837, COSV100387023; called by muse, mutect2, varscan2
- USP28 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 31/291 reads (11%) | catalogued as rs1389829322, COSV50188515; called by muse, mutect2, varscan2
- USP31 | c.3743C>T p.A1248V | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs775233246; called by muse, mutect2, varscan2
- USP35 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 64/514 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1189398801, COSV71572621; called by muse, mutect2, varscan2
- USP40 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs750860688; called by muse, mutect2, varscan2
- USP43 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs745449130; called by muse, mutect2, varscan2
- UTS2R | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 100/765 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1343320380; called by muse, mutect2, varscan2
- VARS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766338883; called by muse, mutect2
- VWA5B2 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 64/606 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1388941277; called by muse, mutect2
- WBP1L | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 47/389 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs146918058; called by muse, mutect2, varscan2
- WDR1 | c.737G>A p.S246N (on ENST00000382452; = p.S106N on NM_005112.5) | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.815); catalogued as rs1291985568; called by muse, mutect2, varscan2
- WDR24 | c.1241G>A p.R414H (on ENST00000248142; = p.R284H on NM_032259.4) | Missense Mutation (SNP) | VAF 61/498 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs368177810; called by muse, mutect2, varscan2
- WDR33 | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 62/495 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.811); catalogued as rs747809897; called by muse, varscan2
- WDR62 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1300094741; called by muse, mutect2, varscan2
- WFIKKN1 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 57/603 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as rs148475508; called by muse, mutect2
- WIZ | c.5336G>A p.R1779H (on ENST00000673675 / NM_001371589.1; = p.R684H on NM_021241.3) | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs761882261, COSV54608450; called by muse, mutect2
- YTHDC1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 66/557 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60010414; called by muse, mutect2, varscan2
- ZBED4 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 56/475 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781774175, COSV53466300; called by muse, mutect2, varscan2
- ZC3H3 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 92/664 reads (14%) | catalogued as rs764083420; called by muse, mutect2, varscan2
- ZCRB1 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026105639; called by muse, varscan2
- ZFAND2B | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 38/358 reads (11%) | catalogued as rs1315609005; called by muse, mutect2, varscan2
- ZFHX3 | c.6016C>A p.H2006N | Missense Mutation (SNP) | VAF 50/549 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99064650; called by muse, mutect2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 56/440 reads (13%) | catalogued as rs761578656; called by mutect2, varscan2
- ZFHX4 | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 62/517 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1219519847; called by muse, varscan2
- ZFP92 | c.327del p.A111Pfs*274 | Frame Shift Del (DEL) | VAF 65/647 reads (10%) | catalogued as COSV58598507; called by mutect2, pindel, varscan2
- ZFP92 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 68/854 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs782495626, COSV58598992; called by muse, mutect2
- ZFR2 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 82/679 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1229818934, COSV53597103; called by muse, mutect2, varscan2
- ZFYVE1 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59613022; called by muse, varscan2
- ZIC1 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 95/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1335188281, COSV51551824, COSV51558768; called by muse, mutect2, varscan2
- ZIM3 | c.1318del p.T440Pfs*98 | Frame Shift Del (DEL) | VAF 49/437 reads (11%) | catalogued as rs760126796, COSV99517559, COSV99518191, COSV99518981; called by mutect2, pindel, varscan2
- ZKSCAN2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 52/412 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs756355033; called by muse, mutect2, varscan2
- ZKSCAN3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 79/576 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52852213; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072del p.N691Mfs*12 | Frame Shift Del (DEL) | VAF 59/457 reads (13%) | catalogued as rs556762260; called by mutect2, pindel, varscan2
- ZMAT5 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs141136441; called by muse, mutect2, varscan2
- ZMYND8 | c.3539G>A p.R1180Q (on ENST00000311275 / NM_001363741.2; = p.R1154Q on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs766336129, COSV53695007; called by muse, mutect2, varscan2
- ZNF282 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1271073264, COSV50483783; called by muse, varscan2
- ZNF3 | c.677del p.K226Sfs*199 | Frame Shift Del (DEL) | VAF 66/604 reads (11%) | catalogued as rs1218389307; called by mutect2, pindel, varscan2
- ZNF335 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs781750860, COSV59819260; called by muse, mutect2, varscan2
- ZNF423 | c.1546G>A p.A516T (on ENST00000563137 / NM_001379286.1; = p.A508T on NM_015069.4) | Missense Mutation (SNP) | VAF 68/550 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs1363154257, COSV52178435, COSV99281198; called by muse, mutect2, varscan2
- ZNF440 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 51/465 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs368965098; called by muse, mutect2, varscan2
- ZNF462 | c.5171C>T p.A1724V | Missense Mutation (SNP) | VAF 60/587 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1396814594, COSV52947585; called by muse, varscan2
- ZNF469 | c.7930G>A p.A2644T (on ENST00000437464; = p.A2672T on NM_001367624.2) | Missense Mutation (SNP) | VAF 66/552 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1302533609; called by muse, mutect2, varscan2
- ZNF503 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 57/504 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV65307932; called by muse, mutect2, varscan2
- ZNF516 | c.2255C>A p.S752Y | Missense Mutation (SNP) | VAF 41/523 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs377559097; called by muse, mutect2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 36/270 reads (13%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF585B | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV57216623; called by muse, mutect2
- ZNF596 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141776606, COSV57654812, COSV57655483; called by muse, mutect2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 44/372 reads (12%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF689 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 82/627 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236880597, COSV99788091; called by muse, mutect2, varscan2
- ZNF71 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 71/605 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1169211321; called by muse, mutect2, varscan2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 28/241 reads (12%) | catalogued as rs781412139; called by mutect2, varscan2
- ZNF816 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as rs1011476120; called by muse, mutect2
- ZNF865 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 86/681 reads (13%) | SIFT tolerated (0.12); catalogued as rs756303683; called by muse, mutect2, varscan2
- ZP3 | c.1052G>A p.R351H (on ENST00000394857 / NM_001110354.2; = p.R300H on NM_007155.6) | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs377699467; called by muse, mutect2
- ZSCAN31 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs199921201; called by muse, mutect2
- ZXDB | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 74/710 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66493355; called by muse, mutect2, varscan2
- ABCD1 | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 81/551 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC004922.1 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 64/459 reads (14%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- ACAP3 | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACOT9 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ACTL9 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 76/583 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ADAD1 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ADAMTS17 | c.14C>A p.A5D | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2
- ADAMTS20 | c.4520A>G p.Q1507R | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS6 | c.2853dup p.E952Rfs*19 | Frame Shift Ins (INS) | VAF 43/404 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.2265C>A p.C755* | Nonsense Mutation (SNP) | VAF 38/360 reads (11%) | called by mutect2, varscan2
- AFDN | c.3673A>G p.T1225A | Missense Mutation (SNP) | VAF 59/430 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGPAT5 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ALG10B | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- AMER2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 77/658 reads (12%) | called by muse, mutect2, varscan2
- ANKDD1A | c.33C>T p.G11= | Splice Region (SNP) | VAF 43/351 reads (12%) | called by muse, mutect2, varscan2
- ANKRD50 | c.2032A>G p.R678G | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD62 | c.2029C>A p.L677I | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AOAH | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- AP2B1 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APBA1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 48/447 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC2 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 77/625 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- APEX2 | c.962G>A p.C321Y | Missense Mutation (SNP) | VAF 56/658 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.405); called by muse, mutect2
- API5 | c.856-1G>T p.X286_splice | Splice Site (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- APMAP | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- APOL5 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 71/606 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ARHGAP23 | c.2555del p.G852Afs*70 | Frame Shift Del (DEL) | VAF 27/235 reads (11%) | called by mutect2, varscan2
- ARHGAP27 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 76/563 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF19 | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 76/736 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ARHGEF4 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 52/464 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARID1B | c.3547del p.Q1183Sfs*15 | Frame Shift Del (DEL) | VAF 59/457 reads (13%) | called by mutect2, pindel, varscan2
- ASPH | c.1899dup p.G634Rfs*5 | Frame Shift Ins (INS) | VAF 33/280 reads (12%) | called by mutect2, pindel, varscan2
- ATE1 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ATG2A | c.4418del p.G1473Afs*14 | Frame Shift Del (DEL) | VAF 63/616 reads (10%) | called by mutect2, pindel
- ATP1A2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ATRIP | c.2360A>C p.E787A (on ENST00000320211 / NM_130384.3; = p.E760A on NM_032166.4) | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- AXIN2 | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 58/614 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2
- B3GAT1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 82/639 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCL2L14 | c.100_102del p.H34del | In Frame Del (DEL) | VAF 48/432 reads (11%) | called by pindel, varscan2
- BEST4 | c.1038del p.A347Lfs*38 | Frame Shift Del (DEL) | VAF 60/499 reads (12%) | called by mutect2, pindel, varscan2
- BEX2 | c.87A>C p.Q29H | Missense Mutation (SNP) | VAF 76/561 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BMX | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 53/629 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRD7 | c.1814T>C p.I605T | Missense Mutation (SNP) | VAF 35/455 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- BRPF1 | c.3371dup p.L1125Tfs*25 | Frame Shift Ins (INS) | VAF 53/531 reads (10%) | called by mutect2, pindel, varscan2
- BZW1 | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- C10orf120 | c.762dup p.C255Mfs*8 | Frame Shift Ins (INS) | VAF 39/366 reads (11%) | called by mutect2, varscan2
- C11orf80 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 80/669 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- C12orf40 | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C17orf97 | c.268del p.R90Gfs*20 | Frame Shift Del (DEL) | VAF 53/425 reads (12%) | called by mutect2, varscan2
- C1orf116 | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 51/459 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- C1orf232 | c.288del p.S97Rfs*81 | Frame Shift Del (DEL) | VAF 59/510 reads (12%) | called by pindel, varscan2
- C6orf132 | c.776A>T p.K259I | Missense Mutation (SNP) | VAF 56/563 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- C7 | c.2129A>T p.N710I | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2
- C7orf57 | c.349_350+2del p.X117_splice | Splice Site (DEL) | VAF 36/338 reads (11%) | called by mutect2, pindel, varscan2
- CACNA1C | c.6490G>A p.A2164T (on ENST00000399634 / NM_001167625.1; = p.A2093T on NM_000719.7) | Missense Mutation (SNP) | VAF 97/655 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMK1D | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CBR1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 82/577 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CC2D2A | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- CCDC117 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.1495del p.T499Hfs*15 | Frame Shift Del (DEL) | VAF 36/390 reads (9%) | called by mutect2, pindel
- CCDC175 | c.642del p.K214Nfs*9 | Frame Shift Del (DEL) | VAF 50/392 reads (13%) | called by mutect2, varscan2
- CCDC8 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 61/646 reads (9%) | called by muse, mutect2
- CCDC8 | c.612del p.K205Sfs*2 | Frame Shift Del (DEL) | VAF 60/646 reads (9%) | called by mutect2, pindel
- CCNT1 | c.1439T>C p.I480T | Missense Mutation (SNP) | VAF 49/419 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CCR10 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 75/639 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CCR2 | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CCR5 | c.67del p.I23Sfs*3 | Frame Shift Del (DEL) | VAF 41/321 reads (13%) | called by mutect2, pindel, varscan2
- CD99 | c.164T>C p.L55S | Missense Mutation (SNP) | VAF 55/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CDC42BPG | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 104/716 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDK15 | c.291del p.F97Lfs*8 (on ENST00000652192 / NM_001366386.2; = p.F46Lfs*8 on NM_139158.2) | Frame Shift Del (DEL) | VAF 46/352 reads (13%) | called by mutect2, pindel, varscan2
- CDK3 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 60/471 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDK5R2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 77/573 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDV3 | c.465T>G p.I155M | Missense Mutation (SNP) | VAF 35/425 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.386); called by muse, mutect2
- CELSR3 | c.4585C>T p.R1529C | Missense Mutation (SNP) | VAF 61/527 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CENPB | c.1204A>G p.K402E | Missense Mutation (SNP) | VAF 64/512 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); called by muse, varscan2
- CEP85 | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 53/453 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CEP85L | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP44 | c.4758del p.V1587* | Frame Shift Del (DEL) | VAF 21/224 reads (9%) | called by mutect2, pindel
- CHDH | c.1419del p.F473Lfs*26 | Frame Shift Del (DEL) | VAF 42/414 reads (10%) | called by mutect2, pindel, varscan2
- CHMP3 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHPF2 | c.1919del p.P640Rfs*21 | Frame Shift Del (DEL) | VAF 80/592 reads (14%) | called by mutect2, varscan2
- CHRDL1 | c.960dup p.A321Sfs*10 (on ENST00000372045; = p.A327Sfs*10 on NM_145234.4) | Frame Shift Ins (INS) | VAF 27/326 reads (8%) | called by mutect2, pindel
- CLCA1 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2
- CLIC4 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
958 further variants in this file (480 protein-altering or splice-affecting, 417 silent, 61 other) are not listed here.
